Somatic mutation profile of tumor specimen 0DON56 from CCDI case PBCCST, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.1 years (5,869 days).
Specimen 0DON56: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c3cbb7a4-aaa1-4767-b766-3df8f5ec32f4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DON4U (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/704fedc0-0182-4d35-be59-d4702f0745e1

The open-access MAF lists 27 somatic variants for this specimen: 17 protein-altering or splice-affecting, 6 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 6, 5'UTR 2, Intron 2, Splice Region 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>G p.R132G | Missense Mutation (SNP) | VAF 255/731 reads (35%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 426/1037 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.764T>C p.I255T | Missense Mutation (SNP) | VAF 248/711 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs876659675, COSV52685038, COSV52712740, COSV52714133; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- CDC42BPB | c.5059G>A p.G1687S | Missense Mutation (SNP) | VAF 417/975 reads (43%) | SIFT tolerated (0.96); PolyPhen benign (0.041); catalogued as rs767627879, COSV100141614; called by muse, mutect2, varscan2
- SPEN | c.7018C>T p.R2340C | Missense Mutation (SNP) | VAF 265/833 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs780023631; called by muse, mutect2, varscan2
- USP19 | c.2338C>T p.R780C | Missense Mutation (SNP) | VAF 263/671 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs772752404; called by muse, mutect2, varscan2
- USP6 | c.4112T>C p.I1371T | Missense Mutation (SNP) | VAF 811/2072 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.237); catalogued as rs1337525183, COSV99031788; called by muse, mutect2, varscan2
- ZNF169 | c.311C>T p.S104L | Missense Mutation (SNP) | VAF 124/1144 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs546667553, COSV61763246; called by muse, mutect2, varscan2
- ATRX | c.1982del p.T661Ifs*4 | Frame Shift Del (DEL) | VAF 439/757 reads (58%) | called by mutect2, pindel, varscan2
- GOLGA8Q | c.1240A>G p.T414A | Missense Mutation (SNP) | VAF 353/507 reads (70%) | SIFT tolerated (0.2); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- GRIN3B | c.2198+1G>A p.X733_splice | Splice Site (SNP) | VAF 216/587 reads (37%) | called by muse, mutect2, varscan2
- MAPK10 | c.188A>G p.N63S (on ENST00000359221 / NM_001351625.2; = p.N101S on NM_002753.5) | Missense Mutation (SNP) | VAF 193/1909 reads (10%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.858); called by muse, mutect2
- MARK3 | c.370A>G p.T124A | Missense Mutation (SNP) | VAF 264/762 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- MUC16 | c.30203C>T p.P10068L | Missense Mutation (SNP) | VAF 389/853 reads (46%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- PTPRB | c.2453-8C>A | Splice Region (SNP) | VAF 221/483 reads (46%) | called by muse, mutect2, varscan2
- SLC9B1 | c.620T>C p.M207T | Missense Mutation (SNP) | VAF 36/1104 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2
- UNC13B | c.2612A>G p.D871G | Missense Mutation (SNP) | VAF 196/528 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- BTD | c.1188C>T p.H396= | Silent (SNP) | VAF 264/781 reads (34%) | catalogued as rs372039874; called by muse, mutect2, varscan2
- DELE1 | c.777C>T p.G259= | Silent (SNP) | VAF 425/1240 reads (34%) | catalogued as rs765620157, COSV99520067; called by muse, mutect2, varscan2
- MYH4 | c.4854C>T p.I1618= | Silent (SNP) | VAF 524/1376 reads (38%) | catalogued as COSV55124871; called by muse, mutect2, varscan2
- PRRC2C | c.3777A>G p.R1259= (on ENST00000367742; = p.R1257= on NM_015172.4) | Silent (SNP) | VAF 58/1434 reads (4%) | called by muse, mutect2
- SSB | c.648G>A p.K216= | Silent (SNP) | VAF 24/889 reads (3%) | called by muse, mutect2
- TUBAL3 | c.27C>T p.I9= | Silent (SNP) | VAF 252/702 reads (36%) | catalogued as rs556747045; called by muse, mutect2, varscan2
- ACO2 | c.941-18G>A | Intron (SNP) | VAF 322/838 reads (38%) | catalogued as rs376182038; called by muse, mutect2, varscan2
- EIF4A3 | c.-87_-86insCAGTGAGGTCGGCAGCGGCACAGCGAGGTCGGCAGCGGCA | 5'UTR (INS) | VAF 11/120 reads (9%) | called by mutect2, varscan2*
- PPP2R3A | c.1996-3657C>T | Intron (SNP) | VAF 432/1282 reads (34%) | catalogued as rs769901380, COSV53861783; called by muse, mutect2, varscan2
- RETNLB | c.-33T>A | 5'UTR (SNP) | VAF 59/977 reads (6%) | called by muse, mutect2
